Somatic mutation profile of tumor specimen ALCH-B2TE-TTP1-A (aliquot ALCH-B2TE-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2TE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.7 years (22,899 days).
Specimen ALCH-B2TE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0d0be91-ae3d-46b6-bfd4-c25e6c00d625.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2TE-NB1-A (Blood Derived Normal), aliquot ALCH-B2TE-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4df06869-5171-446d-8e67-89898d448945

The open-access MAF lists 65 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 10, Intron 3, Splice Site 2, RNA 2, Nonsense Mutation 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSH1 | c.455G>A p.G152E | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.121); catalogued as rs755160294; called by muse, mutect2
- F8 | c.1966T>A p.W656R | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM080282, CM080284; called by muse, mutect2
- FCAR | c.591C>A p.Y197* | Nonsense Mutation (SNP) | VAF 6/109 reads (6%) | catalogued as rs1264921322; called by muse, mutect2
- KIR2DL1 | c.1037C>A p.S346Y | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.461); catalogued as rs1279197049; called by muse, mutect2
- KRTAP13-2 | c.101T>A p.L34Q | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as rs945078100; called by muse, mutect2
- MCM4 | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1160424466, COSV100031121; called by muse, mutect2
- PCDHA2 | c.1233C>A p.S411R | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.16); catalogued as rs782096647, COSV65369099; called by muse, mutect2
- SMOC1 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV62762066; called by muse, mutect2
- SPTA1 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.833); catalogued as rs993458519; called by muse, mutect2
- UBA6 | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.69); catalogued as rs766877225; called by muse, mutect2
- USP9X | c.554A>G p.H185R | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100199335; called by muse, mutect2
- YEATS2 | c.2164G>T p.V722F | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV59366276; called by muse, mutect2
- ZNF711 | c.732A>G p.I244M | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52158472; called by muse, mutect2
- ALMS1 | c.2668G>T p.V890F | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.112); called by muse, mutect2
- ASXL3 | c.4661C>A p.A1554D | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2
- CEMIP2 | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHN2 | c.144+1G>T p.X48_splice | Splice Site (SNP) | VAF 9/206 reads (4%) | called by muse, mutect2
- DCAF12L2 | c.984C>A p.H328Q | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DMD | c.4140C>A p.H1380Q | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DST | c.2002C>A p.P668T (on ENST00000361203 / NM_001374722.1; = p.P342T on NM_001723.6) | Missense Mutation (SNP) | VAF 14/302 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2
- FLNB | c.7238G>T p.G2413V | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GNS | c.514T>G p.W172G | Missense Mutation (SNP) | VAF 24/537 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPAM | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 19/380 reads (5%) | called by muse, mutect2
- GPATCH11 | c.684A>T p.E228D (on ENST00000409774; = p.E206D on NM_174931.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2
- HECTD4 | c.6880G>T p.D2294Y | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IL17REL | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.173); called by muse, mutect2
- IQCB1 | c.1745A>T p.E582V | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2
- IQCB1 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); called by muse, mutect2
- KRT1 | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 14/296 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- LRRK2 | c.5809G>T p.A1937S | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- MICAL3 | c.4521G>C p.E1507D | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2
- NES | c.1730G>T p.R577M | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2
- OR2M5 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAPPA2 | c.4531G>T p.D1511Y | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PDYN | c.391A>T p.R131W | Missense Mutation (SNP) | VAF 14/383 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.841); called by muse, mutect2
- PLEKHA5 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); called by muse, mutect2
- POTEE | c.2065A>G p.N689D | Missense Mutation (SNP) | VAF 15/450 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- PREX2 | c.4483A>G p.T1495A | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.017); called by muse, mutect2
- RANBP2 | c.6481G>T p.G2161C | Missense Mutation (SNP) | VAF 34/1185 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC4A8 | c.2901G>C p.W967C | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLITRK2 | c.2255C>A p.P752H | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); called by muse, mutect2
- SRGAP3 | c.752A>C p.N251T | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2
- ST18 | c.140T>C p.L47S | Missense Mutation (SNP) | VAF 10/271 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- TLL2 | c.1259C>A p.P420H | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2
- TMEM67 | c.2440-2A>T p.X814_splice | Splice Site (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- TRIM67 | c.1990C>A p.P664T | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- TRIP11 | c.3974A>G p.Q1325R | Missense Mutation (SNP) | VAF 22/351 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.05); called by muse, mutect2
- VSTM2L | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 9/185 reads (5%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.989); called by muse, mutect2
- ASXL3 | c.4662C>A p.A1554= | Silent (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- BDP1 | c.2688A>T p.I896= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- CSMD3 | c.675A>T p.T225= | Silent (SNP) | VAF 12/332 reads (4%) | catalogued as COSV52320248; called by muse, mutect2
- CYCS | c.210G>A p.E70= | Silent (SNP) | VAF 18/498 reads (4%) | catalogued as rs1336522326; called by muse, mutect2
- EPHA5 | c.405G>T p.R135= | Silent (SNP) | VAF 18/193 reads (9%) | called by muse, mutect2
- LAMC3 | c.3297G>A p.K1099= | Silent (SNP) | VAF 7/160 reads (4%) | called by muse, mutect2
- NLRP4 | c.1644G>T p.V548= | Silent (SNP) | VAF 7/109 reads (6%) | catalogued as COSV56720951; called by muse, mutect2
- OR2H2 | c.240G>A p.L80= | Silent (SNP) | VAF 6/91 reads (7%) | called by muse, mutect2
- SHOX | c.768C>T p.S256= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs974381093; called by muse, mutect2, varscan2
- SLC44A5 | c.864C>T p.H288= | Silent (SNP) | VAF 8/244 reads (3%) | called by muse, mutect2
- C8orf87 | n.322G>T | RNA (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- DENND10P1 | n.997A>T | RNA (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
- ELFN1 | c.-456+5359G>T | Intron (SNP) | VAF 6/62 reads (10%) | called by muse, varscan2
- RNF8 | c.*85G>T | 3'UTR (SNP) | VAF 7/135 reads (5%) | called by muse, mutect2
- SCN2A | c.-12C>G | 5'UTR (SNP) | VAF 15/304 reads (5%) | called by muse, mutect2
- SUN5 | c.340+35G>T | Intron (SNP) | VAF 9/184 reads (5%) | called by muse, mutect2
- ZMYND12 | c.975+13A>T | Intron (SNP) | VAF 17/248 reads (7%) | called by muse, mutect2
